Gene-level copy-number profile of tumor specimen C3L-02619-01 from CPTAC case C3L-02619, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 70.2 years (25,633 days).
Specimen C3L-02619-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3826b699-e496-470f-bf09-0df113fb6e99.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02619-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/9d02ae50-d4a4-4f93-8e3a-cd1db42d0768

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 53; copy number 1: 2,970; copy number 2: 37,246; copy number 3: 11,477; copy number 4: 5,073; copy number 5: 2,008; copy number 6: 42; copy number 8: 2; copy number 9: 8; copy number 12: 4; copy number 20: 1; copy number 24: 26.

Homozygous deletions (total copy number 0; autosomes only): 53 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,272,393–25,330,445, 2 genes (within-gene range 0–2): RHD, SDHDP6.
- chr8:3,700,492–3,700,628, 1 gene (within-gene range 0–2): RNA5SP251.
- chr9:21,802,636–26,895,970, 43 genes (within-gene range 0–2): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1, AL365204.2, AL365204.3, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P.
- chr9:61,581,813–61,582,675, 1 gene: AL935212.3.
- chr16:32,289,547–32,310,555, 1 gene: AC133548.2.
- chr16:32,388,135–32,478,250, 5 genes: AC138915.2, PABPC1P13, AC138915.3, AC138915.1, ABCD1P3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,091 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:17,284,292–19,358,623, 18 genes, copy number 6: ZFYVE9P2, PSMC1P10, RAD51AP2, VSNL1, SMC6, GEN1, MSGN1, KCNS3, AC079802.1, AC079148.1, RDH14, NT5C1B-RDH14, NT5C1B, RNU6-1215P, AC106053.1, LINC01376, MIR4757, OSR1.
- chr3:93,843,764–95,683,193, 16 genes, copy number 6: RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2, ARMC10P1, AC140059.1, WDR82P1, LINC00879, RPS18P6, MTHFD2P1.
- chr3:130,048,143–153,980,186, 388 genes, copy number 5–12 (within-gene range 4–12) (broad region; genes not listed).
- chr3:169,083,499–198,123,232, 574 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–45,098,647, 675 genes, copy number 5 (broad region; genes not listed).
- chr5:45,890,216–52,080,987, 26 genes, copy number 5: AC122694.1, EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1, AC010478.1, ISL1, HMGB1P47, AC091860.1, AC022433.1, AC091860.2, RNA5SP182, KATNBL1P4, AC091903.1, LINC02118.
- chr6:905,445–909,006, 1 gene, copy number 6: AL356130.1.
- chr6:61,574,328–61,681,049, 2 genes, copy number 9 (within-gene range 1–9): MTRNR2L9, KHDRBS2-OT1.
- chr7:90,466,424–91,210,590, 1 gene, copy number 6 (within-gene range 2–9): CDK14.
- chr7:90,590,619–93,361,123, 40 genes, copy number 6–24: AC002456.1, TVP23CP1, AC002458.1, PTP4A1P3, FZD1, AC079760.2, NIPA2P1, AC079760.1, AC000058.1, MTERF1, AKAP9, CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1, TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1, RN7SL7P, SAMD9, SAMD9L, HEPACAM2, VPS50.
- chr7:94,278,680–96,709,891, 38 genes, copy number 5–8: AC002074.1, COL1A2, RNU6-1328P, CASD1, SGCE, PEG10, RPS3AP25, RNU6-956P, ATP5PBP2, GRPEL2P3, RN7SKP129, ARF1P1, PPP1R9A, HINT1P2, AC002429.1, PPP1R9A-AS1, RNU4-16P, PON1, AC004022.2, AC004022.1, PON3, PON2, AC005021.1, AC004012.1, ASB4, AC002451.2, AC002451.1, PDK4, DYNC1I1, AC002540.1, SLC25A13, MIR591, AC096775.1, AC084368.1, RNU6-532P, RNU6-364P, RNU7-188P, SEM1.
- chr8:34,174,886–34,346,731, 4 genes, copy number 5: AC087855.2, AC090993.1, AC087855.1, RPL10AP3.
- chr8:37,843,268–39,928,790, 57 genes, copy number 5 (within-gene range 3–5): BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1.
- chr8:39,914,229–39,920,890, 2 genes, copy number 5 (within-gene range 3–5): AC007991.2, AC007991.4.
- chr8:49,740,216–49,820,944, 2 genes, copy number 12–20: PSAT1P1, AC113145.1.
- chr10:2,150,480–2,315,075, 4 genes, copy number 5: AL441943.2, LINC02662, RNU6-576P, LINC00701.
- chr12:52,314,301–52,493,257, 12 genes, copy number 5: KRT83, KRT89P, KRT85, KRT84, AC078865.1, KRT82, AC055736.1, KRT90P, KRT75, KRT6B, KRT6C, KRT6A.
- chr12:123,671,113–123,708,399, 2 genes, copy number 5: TCTN2, AC117503.1.
- chr22:26,512,537–33,058,381, 229 genes, copy number 5 (within-gene range 2–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,458. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
